Somatic mutation profile of tumor specimen 0DCXBB from CCDI case PBBNCU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.1 years (776 days).
Specimen 0DCXBB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d16536-b128-49c3-bb7b-200eedd0e6e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCXAA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b641f5a5-b725-4554-a5ea-bfc14e114ef3

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 5'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV100652718; called by muse, varscan2
- CCSER2 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 84/610 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56513678; called by muse, varscan2
- GALNS | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 304/660 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs748493501; called by muse, varscan2
- NLGN3 | c.2399C>T p.P800L (on ENST00000358741 / NM_181303.2; = p.P780L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200889500, COSV62445628; called by muse, varscan2
- PCBP4 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 72/688 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1194872241; called by muse, varscan2
- RTP1 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56617762; called by muse, varscan2
- SLIT3 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 102/716 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375040794; called by muse, varscan2
- TAF1 | c.4989G>T p.K1663N (on ENST00000373790 / NM_138923.4; = p.K1684N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/580 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1336715340; called by muse, varscan2
- FKBP10 | c.1257-3C>T | Splice Region (SNP) | VAF 204/406 reads (50%) | called by muse, varscan2
- H1-6 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 119/724 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, varscan2
- OSMR | c.2456A>C p.Q819P | Missense Mutation (SNP) | VAF 74/731 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, varscan2
- SACM1L | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- SHANK1 | c.5116G>A p.G1706S | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, varscan2
- ZBBX | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 102/672 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, varscan2
- ARHGEF1 | c.189G>A p.L63= | Silent (SNP) | VAF 188/627 reads (30%) | called by muse, varscan2
- CCDC166 | c.798G>A p.A266= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as rs1311382410, COSV101545820; called by muse, varscan2
- EN1 | c.231C>T p.H77= | Silent (SNP) | VAF 60/464 reads (13%) | catalogued as rs778201908, COSV54631310; called by muse, varscan2
- OSMR | c.2457G>A p.Q819= | Silent (SNP) | VAF 72/728 reads (10%) | called by muse, varscan2
- CCT6A | c.-2C>G | 5'UTR (SNP) | VAF 85/696 reads (12%) | catalogued as rs779908729; called by muse, varscan2
- DLG2 | c.205-21906C>T | Intron (SNP) | VAF 95/750 reads (13%) | catalogued as rs1156725058; called by muse, varscan2
